HCMI case HCM-EXPT-1064-C18 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/547967e5-7452-439b-a60a-a2526f0ac2cb

Demographics
Sex at birth: male; Year of birth: 1941.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.2; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Ascending colon; Classification of tumor: primary; Age at diagnosis: 76.6 years (27,979 days); Prior treatment: No.
   Recorded as not given: neoadjuvant treatment (type not reported).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-EXPT-1064-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-EXPT-1064-C18-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 34; Percent tumor nuclei: 67; Percent normal cells: 17; Percent necrosis: 18; Percent stromal cells: 31; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 0.
  Slide HCM-EXPT-1064-C18-01A-01-S1-HE: Section location: Top; Percent tumor cells: 19; Percent tumor nuclei: 50; Percent normal cells: 19; Percent necrosis: 40; Percent stromal cells: 22; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 1.
